Somatic mutation profile of tumor specimen 7e3d5ae0-3dcc-4207-8dd2-59ab4b (aliquot 7e3d5ae0-3dcc-4207-8dd2-59ab4b_D6_1) from CPTAC case 11CO044, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA.
Specimen 7e3d5ae0-3dcc-4207-8dd2-59ab4b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2beeac38-1c73-4b72-b1a0-8388d3cf3dd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1b7c35d8-3f4b-4d7c-acfe-049847 (Blood Derived Normal), aliquot 1b7c35d8-3f4b-4d7c-acfe-049847_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e173d14e-cce6-43bf-a72d-e010fe372fc7

The open-access MAF lists 227 somatic variants for this specimen: 158 protein-altering or splice-affecting, 44 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 44, Nonsense Mutation 13, Intron 13, Frame Shift Ins 7, Splice Site 4, Splice Region 4, 5'Flank 4, 3'UTR 4, Frame Shift Del 3, 5'UTR 3, In Frame Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 60/151 reads (40%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.7566C>A p.C2522* | Nonsense Mutation (SNP) | VAF 127/289 reads (44%) | catalogued as rs1555394235; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 109/249 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 146/260 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 248/446 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AIMP1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs147167431; called by muse, mutect2, varscan2
- ALK | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766541301, COSV66555825, COSV66589818; called by muse, mutect2, varscan2
- AMPD3 | c.1360G>A p.A454T (on ENST00000396553 / NM_001025389.2; = p.A463T on NM_000480.3) | Missense Mutation (SNP) | VAF 313/932 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746887841; called by muse, mutect2, varscan2
- ANKRD62 | c.1518A>G p.I506M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1397910150; called by muse, mutect2, varscan2
- APC | c.4364dup p.N1455Kfs*2 | Frame Shift Ins (INS) | VAF 29/186 reads (16%) | catalogued as COSV57364337; called by mutect2, pindel, varscan2
- ASTN1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 100/465 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1397720198, COSV56076060; called by muse, mutect2, varscan2
- BDNF | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.985); catalogued as rs779925777; called by muse, mutect2, varscan2
- BRPF3 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs1337109208, COSV60206587; called by muse, mutect2
- BTBD8 | c.2825C>T p.P942L (on ENST00000636805 / NM_001376131.1; = p.P429L on NM_015237.4) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1333862464; called by muse, mutect2, varscan2
- C4orf54 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.106); catalogued as rs1331693962; called by muse, mutect2, varscan2
- CACNA1B | c.1185G>A p.A395= | Splice Region (SNP) | VAF 26/192 reads (14%) | catalogued as rs376560399, COSV99495352; called by muse, mutect2, varscan2
- CALY | c.329A>G p.Q110R | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs757530345; called by muse, mutect2, varscan2
- CATSPER2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754652195, COSV58661001; called by muse, mutect2, varscan2
- CEP250 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.738); catalogued as rs771268588; called by muse, mutect2, varscan2
- CLSTN2 | c.786A>C p.Q262H | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs267599628, COSV71721475; called by muse, mutect2, varscan2
- CNTN4 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 187/510 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs772184755; called by muse, mutect2, varscan2
- COPA | c.1302G>A p.S434= | Splice Region (SNP) | VAF 48/196 reads (24%) | catalogued as COSV54109835; called by muse, mutect2, varscan2
- CUBN | c.2158T>A p.F720I | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64718815; called by muse, varscan2
- CUX2 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs766272518; called by muse, mutect2, varscan2
- DCP1B | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs777121803; called by muse, mutect2, varscan2
- DCT | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs376196399; called by muse, mutect2, varscan2
- DDI1 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 166/430 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56369127; called by muse, mutect2, varscan2
- DMD | c.1378T>G p.L460V | Missense Mutation (SNP) | VAF 164/350 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55894286; called by muse, mutect2, varscan2
- DNAH3 | c.7315G>A p.G2439R | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376902629; called by muse, mutect2, varscan2
- DNAH5 | c.7943C>T p.A2648V | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs201939338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1B | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs748499096; called by muse, mutect2, varscan2
- DPYD | c.2632A>G p.S878G | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs762911226, COSV100928475, COSV64612305; ClinVar: uncertain significance; called by mutect2, varscan2
- EPHA6 | c.1781T>A p.V594D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV101065206, COSV67571249; called by muse, mutect2, varscan2
- FAT3 | c.12016G>A p.A4006T | Missense Mutation (SNP) | VAF 76/459 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1467357873, COSV53111015; called by muse, mutect2, varscan2
- FERD3L | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51761976, COSV51764624; called by muse, varscan2
- GAS2 | c.181T>G p.L61V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53409027; called by muse, mutect2, varscan2
- HERC2 | c.4959_4961del p.M1654del | In Frame Del (DEL) | VAF 41/248 reads (17%) | catalogued as rs1213623760; called by mutect2, pindel, varscan2
- KLHDC7A | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 206/403 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV68769041; called by muse, mutect2, varscan2
- KRT75 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368136976; called by muse, mutect2, varscan2
- L1CAM | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 235/531 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as rs1320396543; called by muse, mutect2, varscan2
- LONRF2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs751349231, COSV101110922; called by muse, mutect2, varscan2
- MAGEB5 | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV66869022; called by muse, mutect2, varscan2
- METTL21C | c.520dup p.E174Gfs*15 | Frame Shift Ins (INS) | VAF 124/382 reads (32%) | catalogued as rs760847518; called by mutect2, varscan2
- MPDZ | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767520042, COSV59940001; called by muse, mutect2, varscan2
- NRSN2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs905109408, COSV66526790; called by muse, mutect2, varscan2
- OR14I1 | c.7A>C p.N3H | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449873245; called by muse, mutect2, varscan2
- OR2G6 | c.634T>G p.L212V | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.08); catalogued as COSV58574870; called by muse, mutect2, varscan2
- PDZD8 | c.2125A>T p.R709W | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57827448; called by muse, mutect2, varscan2
- PHKA1 | c.2921G>T p.R974L | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59801415; called by muse, mutect2, varscan2
- PLEC | c.8084G>A p.R2695Q (on ENST00000322810 / NM_201380.4; = p.R2585Q on NM_000445.5) | Missense Mutation (SNP) | VAF 134/850 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs782713454, COSV100511782; called by muse, mutect2, varscan2
- PLXNA3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1557204559, COSV63754720; called by muse, mutect2, varscan2
- RDH13 | c.890C>T p.A297V (on ENST00000415061 / NM_001145971.2; = p.A226V on NM_138412.4) | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV52562824, COSV99401636; called by muse, mutect2, varscan2
- SEMA3D | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs754910513, COSV52390098; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- SFXN5 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs771558265; called by muse, mutect2, varscan2
- SIGLEC11 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs889378455; called by muse, mutect2, varscan2
- SLC7A13 | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs780882826, COSV52533275; called by muse, mutect2, varscan2
- SMG8 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs145833675; called by muse, mutect2, varscan2
- SOX9 | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 47/138 reads (34%) | catalogued as COSV55424031; called by muse, mutect2, varscan2
- SPEM2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs369322480; called by muse, mutect2, varscan2
- TGFB2 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV65109598; called by muse, mutect2, varscan2
- TIAM1 | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as rs1423334383; called by muse, mutect2, varscan2
- TPO | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs199694732, CM022257, COSV61101763; called by muse, mutect2, varscan2
- TRIM49B | c.579A>C p.E193D | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV60323424; called by muse, mutect2, varscan2
- TRIM49B | c.979A>T p.S327C | Missense Mutation (SNP) | VAF 64/460 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60321576, COSV60322163, COSV60324412; called by muse, mutect2, varscan2
- TTN | c.21182C>A p.A7061D (on ENST00000591111; = p.A6134D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/264 reads (10%) | PolyPhen possibly damaging (0.908); catalogued as COSV59970165; called by muse, mutect2
- UNC13C | c.3945A>C p.E1315D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV52847570, COSV99524809; called by muse, mutect2, varscan2
- ZFHX4 | c.7373T>G p.L2458R | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.165); catalogued as COSV50589877, COSV51476909; called by muse, mutect2
- ZNF101 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745673350; called by muse, mutect2, varscan2
- ZNF540 | c.1795A>G p.R599G | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100329675, COSV57109044; called by muse, mutect2, varscan2
- ZNF592 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 210/404 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1412394318; called by muse, mutect2, varscan2
- AATF | c.723G>T p.R241S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC092143.1 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 179/1006 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACAN | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 168/324 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ACHE | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 34/583 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ACMSD | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ACTN1 | c.1060A>G p.M354V | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAM28 | c.1103+2T>A p.X368_splice | Splice Site (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- ADGRL3 | c.1217A>T p.K406M (on ENST00000506720 / NM_001322402.2; = p.K338M on NM_015236.6) | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AIFM1 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AMER1 | c.437_438dup p.V147Lfs*24 | Frame Shift Ins (INS) | VAF 111/352 reads (32%) | called by mutect2, pindel, varscan2
- ANTXR1 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 72/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ATP8A2 | c.1732G>T p.V578L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- C5orf22 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC73 | c.2683dup p.T895Nfs*2 | Frame Shift Ins (INS) | VAF 33/133 reads (25%) | called by mutect2, varscan2
- CEP162 | c.3550G>T p.E1184* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- CNPY1 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- COPA | c.3040T>A p.Y1014N | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.5896C>G p.L1966V | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CYP24A1 | c.202_210del p.G68_L70del | In Frame Del (DEL) | VAF 46/505 reads (9%) | called by mutect2, pindel
- DGAT1 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAH7 | c.2158A>C p.K720Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DUSP14 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM186A | c.5836A>T p.S1946C | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- FSIP2 | c.16675T>C p.F5559L | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCDH | c.1037del p.G346Afs*11 | Frame Shift Del (DEL) | VAF 188/518 reads (36%) | called by mutect2, pindel, varscan2
- GON4L | c.1453-1G>T p.X485_splice | Splice Site (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- GRIP1 | c.60A>C p.K20N | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2
- GRIP2 | c.1225G>A p.E409K (on ENST00000619221; = p.E312K on NM_001080423.4) | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- GSG1 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- HERC2 | c.13693A>C p.M4565L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- IRS2 | c.3530T>A p.V1177E | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ITGA5 | c.478T>A p.Y160N | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR3 | c.5887G>T p.E1963* | Nonsense Mutation (SNP) | VAF 62/344 reads (18%) | called by muse, mutect2, varscan2
- KCNH7 | c.2206A>T p.N736Y | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- KCNH8 | c.1256G>C p.S419T | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- KIF14 | c.4769T>G p.L1590W | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- L1TD1 | c.698_713dup p.D238Efs*7 | Frame Shift Ins (INS) | VAF 20/130 reads (15%) | called by mutect2, varscan2
- LMBRD2 | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- MAP3K19 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 55/211 reads (26%) | called by muse, mutect2, varscan2
- MED23 | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- NEIL3 | c.1727T>G p.F576C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEUROD6 | c.350T>A p.L117* | Nonsense Mutation (SNP) | VAF 48/514 reads (9%) | called by muse, mutect2
- NME9 | c.394G>A p.E132K (on ENST00000333911 / NM_001349024.2; = p.E71K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NOTCH3 | c.5519A>C p.E1840A | Missense Mutation (SNP) | VAF 93/459 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NOVA2 | c.279T>G p.N93K | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- NPAS3 | c.1618C>T p.P540S (on ENST00000356141 / NM_001164749.2; = p.P508S on NM_022123.3) | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRARP | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NRK | c.126A>C p.G42= | Splice Region (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- NRK | c.4040A>G p.D1347G | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2
- NUP205 | c.2951_2953del p.R984del | In Frame Del (DEL) | VAF 38/84 reads (45%) | called by mutect2, pindel, varscan2
- OCRL | c.1760T>C p.F587S | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR4D5 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OSBPL11 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCLO | c.3595A>G p.K1199E | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PFKM | c.1769C>A p.A590D | Missense Mutation (SNP) | VAF 208/501 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA5 | c.1296-1G>C p.X432_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- PPP1R9A | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 54/403 reads (13%) | called by muse, mutect2, varscan2
- PRDM7 | c.1032C>A p.C344* | Nonsense Mutation (SNP) | VAF 147/639 reads (23%) | called by muse, mutect2, varscan2
- PRKD1 | c.699A>T p.Q233H | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PROSER1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- PTPDC1 | c.940C>T p.P314S (on ENST00000375360 / NM_177995.3; = p.P366S on NM_152422.4) | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PTPRN | c.114C>T p.H38= | Splice Region (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- RECQL5 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 103/545 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RELN | c.6235T>C p.Y2079H | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- RP1 | c.5526T>A p.C1842* | Nonsense Mutation (SNP) | VAF 42/578 reads (7%) | called by muse, mutect2
- RTRAF | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- SEH1L | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SLC17A2 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC38A4 | c.681_682insG p.F228Vfs*11 | Frame Shift Ins (INS) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- SMR3A | c.356del p.F119Sfs*3 | Frame Shift Del (DEL) | VAF 48/232 reads (21%) | called by mutect2, pindel, varscan2
- SPHKAP | c.3200A>T p.N1067I | Missense Mutation (SNP) | VAF 96/431 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SYNE1 | c.17515C>T p.P5839S (on ENST00000367255 / NM_182961.4; = p.P5768S on NM_033071.3) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAT | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 96/443 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, varscan2
- TMEM63A | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 10/380 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- TRIM64C | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 52/480 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); called by muse, mutect2
- TRPV6 | c.469+1G>A p.X157_splice | Splice Site (SNP) | VAF 58/198 reads (29%) | called by muse, mutect2, varscan2
- UGT2A2 | c.673T>G p.Y225D | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2B11 | c.577T>G p.Y193D | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP17L2 | c.1271T>C p.L424S | Missense Mutation (SNP) | VAF 146/575 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP32 | c.2614_2615del p.L872Kfs*4 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- WDR87 | c.6040G>T p.E2014* | Nonsense Mutation (SNP) | VAF 30/165 reads (18%) | called by muse, mutect2, varscan2
- WFDC3 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XXYLT1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF540 | c.1203T>A p.H401Q | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZNF628 | c.2307G>T p.Q769H | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ZNF729 | c.1333T>G p.S445A | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZSWIM2 | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 65/348 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- AGAP2 | c.1503C>T p.R501= (on ENST00000547588 / NM_001122772.2; = p.R165= on NM_014770.4) | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs368561969; called by muse, mutect2, varscan2
- AP3D1 | c.399G>A p.T133= | Silent (SNP) | VAF 97/224 reads (43%) | catalogued as rs745494333; called by muse, mutect2, varscan2
- ARHGAP22 | c.1371C>T p.G457= | Silent (SNP) | VAF 18/376 reads (5%) | called by muse, mutect2
- ASXL3 | c.5796C>T p.Y1932= | Silent (SNP) | VAF 72/257 reads (28%) | catalogued as COSV52462290; called by muse, mutect2, varscan2
- ATRN | c.3999C>T p.V1333= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs375039387; called by mutect2, varscan2
- C1R | c.715C>A p.R239= (on ENST00000536053 / NM_001354346.2; = p.R225= on NM_001733.7) | Silent (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- CACNA1F | c.4440G>A p.L1480= | Silent (SNP) | VAF 128/567 reads (23%) | catalogued as rs1053797987; called by muse, mutect2, varscan2
- CCDC183 | c.663C>A p.V221= | Silent (SNP) | VAF 30/198 reads (15%) | called by muse, mutect2, varscan2
- DRC7 | c.624C>T p.N208= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as rs201161084, COSV61052909; called by muse, mutect2, varscan2
- DSCAML1 | c.387C>T p.D129= (on ENST00000321322; = p.D69= on NM_020693.4) | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs780150685, COSV58381365; called by muse, mutect2, varscan2
- EML2 | c.1842C>T p.Y614= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as rs780151012; called by muse, mutect2, varscan2
- F8 | c.6423C>A p.T2141= | Silent (SNP) | VAF 33/292 reads (11%) | catalogued as rs781907922; called by muse, mutect2, varscan2
- GLCCI1 | c.1503T>A p.V501= | Silent (SNP) | VAF 141/424 reads (33%) | called by muse, mutect2, varscan2
- GSTM3 | c.345G>C p.L115= | Silent (SNP) | VAF 130/249 reads (52%) | called by muse, mutect2, varscan2
- KIF25 | c.543G>T p.L181= | Silent (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- KRTAP25-1 | c.298A>C p.R100= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs546401866; called by muse, mutect2, varscan2
- LOXHD1 | c.1173C>A p.T391= | Silent (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
- MBOAT4 | c.750T>C p.L250= | Silent (SNP) | VAF 80/238 reads (34%) | called by muse, mutect2, varscan2
- MORF4L2 | c.852C>T p.H284= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1452742479; called by muse, mutect2, varscan2
- MUC16 | c.18C>A p.G6= | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- NPY2R | c.588G>A p.P196= | Silent (SNP) | VAF 76/483 reads (16%) | catalogued as rs780178931, COSV61527343; called by muse, mutect2
- OBSL1 | c.507C>T p.D169= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- OR10G4 | c.660C>T p.I220= | Silent (SNP) | VAF 231/532 reads (43%) | catalogued as rs1338777128, COSV100305045, COSV57977173; called by muse, mutect2, varscan2
- OR10V1 | c.267C>A p.G89= | Silent (SNP) | VAF 68/296 reads (23%) | called by muse, mutect2, varscan2
- PEX5L | c.342G>C p.L114= | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- PIK3C2G | c.1458A>C p.L486= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs768845699; called by muse, varscan2
- PSG7 | c.324G>T p.L108= | Silent (SNP) | VAF 80/399 reads (20%) | catalogued as COSV101343225; called by muse, mutect2, varscan2
- RARG | c.1092C>T p.Y364= | Silent (SNP) | VAF 53/215 reads (25%) | catalogued as rs769206913; called by muse, mutect2, varscan2
- RASGRF1 | c.3630C>T p.D1210= | Silent (SNP) | VAF 69/134 reads (51%) | catalogued as rs767054381; called by muse, mutect2, varscan2
- RYR2 | c.7762T>C p.L2588= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- SACS | c.1806C>G p.A602= | Silent (SNP) | VAF 48/422 reads (11%) | catalogued as COSV66544784; called by muse, mutect2, varscan2
- SEMA3E | c.1819T>C p.L607= | Silent (SNP) | VAF 35/290 reads (12%) | called by muse, mutect2, varscan2
- SLC4A4 | c.2689T>C p.L897= (on ENST00000264485 / NM_001098484.3; = p.L853= on NM_003759.4) | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as COSV52624942; called by muse, mutect2, varscan2
- TACO1 | c.27A>G p.L9= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as rs1437447929; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNRC6C | c.3279G>A p.P1093= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs369485423; called by muse, mutect2, varscan2
- TRANK1 | c.51G>T p.L17= | Silent (SNP) | VAF 64/185 reads (35%) | called by muse, mutect2, varscan2
- TRIM64C | c.1293T>G p.G431= | Silent (SNP) | VAF 54/476 reads (11%) | called by muse, mutect2
- TRPC7 | c.597G>A p.K199= | Silent (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- TRPV4 | c.1884C>T p.Y628= | Silent (SNP) | VAF 86/432 reads (20%) | catalogued as rs369752162; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.51033T>A p.G17011= (on ENST00000591111; = p.G9587= on NM_003319.4) | Silent (SNP) | VAF 43/285 reads (15%) | called by muse, mutect2, varscan2
- USP10 | c.501C>T p.G167= | Silent (SNP) | VAF 169/420 reads (40%) | catalogued as rs527742941; called by muse, mutect2, varscan2
- WDR35 | c.1587C>T p.Y529= (on ENST00000345530 / NM_001006657.2; = p.Y518= on NM_020779.4) | Silent (SNP) | VAF 54/223 reads (24%) | called by muse, mutect2, varscan2
- WRN | c.3621C>A p.G1207= | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- ZIC3 | c.957C>A p.I319= | Silent (SNP) | VAF 105/463 reads (23%) | called by muse, mutect2, varscan2
- AC011448.1 | c.-5C>G | 5'UTR (SNP) | VAF 82/609 reads (13%) | called by muse, mutect2, varscan2
- BNC2 | c.2639+4126A>G | Intron (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- CASP7 | c.-148G>T | 5'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- CCSER1 | c.2217+239149G>T | Intron (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
- COQ7 | c.73+1096A>G | Intron (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2
- CSNK1G2 | c.*121C>T | 3'UTR (SNP) | VAF 37/98 reads (38%) | catalogued as rs1014157433; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14823A>G | Intron (SNP) | VAF 40/160 reads (25%) | called by mutect2, varscan2
- DOCK4 | c.5014-584T>G | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- FRG2KP | chr16:31569256 G>A | 5'Flank (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- GRM1 | c.-8T>C | 5'UTR (SNP) | VAF 34/483 reads (7%) | called by muse, mutect2
- HYDIN | c.11471+840A>G | Intron (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- NOTCH1 | c.*28C>T | 3'UTR (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5167+243C>G | Intron (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- PPDPFL | c.*742G>T | 3'UTR (SNP) | VAF 52/269 reads (19%) | called by muse, mutect2, varscan2
- PPFIA1 | c.264+11599_264+11600insG | Intron (INS) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- RARRES1 | chr3:158732528 G>A | 5'Flank (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158907 G>A | 5'Flank (SNP) | VAF 36/131 reads (27%) | catalogued as rs755028317; called by muse, mutect2, varscan2
- ROBO1 | c.173-79544C>A | Intron (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- SLC12A8 | c.737-82G>A | Intron (SNP) | VAF 128/270 reads (47%) | catalogued as rs534574930; called by muse, mutect2, varscan2
- TMEM155 | chr4:121766321 A>G | 5'Flank (SNP) | VAF 46/282 reads (16%) | called by muse, mutect2
- TMEM235 | c.*146C>A | 3'UTR (SNP) | VAF 30/280 reads (11%) | called by muse, mutect2, varscan2
- VSX1 | c.627+39A>G | Intron (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- WASF4P | n.547A>G | RNA (SNP) | VAF 84/543 reads (15%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.426-4210G>T | Intron (SNP) | VAF 27/189 reads (14%) | called by muse, mutect2, varscan2
- ZNF596 | c.224-22_224-21insG | Intron (INS) | VAF 14/115 reads (12%) | called by mutect2, pindel, varscan2
